Surgical pathology report (de-identified scan), TCGA case TCGA-DD-AAEB, project TCGA-LIHC (Liver Hepatocellular Carcinoma), tissue source site Mayo Clinic - Rochester, specimen TCGA-DD-AAEB-01A (Primary Tumor).

[page 1 of 2]
CLINICAL DIAGNOSIS: Hepatocellular carcinoma suggested

Specimen : Liver and Liver mass

Gross Photo :

GROSS:

Specimen status: Fresh

Operation: Partial hepatectomy and cholecystectomy

Organs:

Liver (17.0 x 7.0 x 4.2 cm, 254.5 gm) and gallbladder (9.1 cm in length and 2.0 cm in diameter)

Lesion: A well-defined round mass (4.7 x 4.0 x 3.7 cm) in liver

Cut surface: Yellowish to green solid and firm mass without necrosis

Gross type:

HCC: Expanding nodular

Resection margin: Not involved grossly (safety margin: 2.0 cm)

Others:

Satellite nodule: No

Remaining parenchyma: Periportal fibrosis (stage 2), mild steatosis

Gross photo: Present

Blocks

T1-4, TB, mass x 5

NB, L, liver parenchyma x 2

RM, resection margin x 1

GB, gallbladder x 1

ICD-O-3

Carcinoma, hepatocellular NOS
8170/3

Site: Liver C22.0

JS 5/20/14

MICROSCOPIC:

Hepatocellular carcinoma: Yes

The worst differentiation II

The major differentiation II

Histologic type: Trabecular

Cell type: Hepatic

Fatty change: Yes (10%)

Fibrous capsule formation: Partial capsule

Capsular infiltration: Yes

Septum formation: No

Surgical resection margin invasion: No, safety margin (2.0 cm)

Serosal invasion: No

Portal vein invasion: No

Microvessel invasion: No

Intrahepatic metastasis: Unknown

Multicentric occurrence: Unknown

NOT reported. Gross:

[page 2 of 2]
Liver, needle, consistent with, hepatocellular carcinoma

Liver, ectomy, hepatocellular carcinoma, moderately differentiated, steatosis, periportal fibrosis

T56000, P10, M81703, moderately differentiated, M50080, periportal fibrosis

Gallbladder, ectomy, chronic cholecystitis

T57000, P10, M43005

Lymph node, regional, biopsy, reactive hyperplasia

T08000, regional, P50, M72200

DIAGNOSIS:

Liver, partial hepatectomy:

Hepatocellular carcinoma, moderately differentiated

Steatosis, mild

Periportal fibrosis (stage 2)

Gallbladder, cholecystectomy: Chronic cholecystitis

Lymph node, regional, biopsy: Reactive hyperplasia (0/1)

Suggestion :

Source: NCI Genomic Data Commons file 199785fe-2f8a-4458-ba9a-8b0fcc012c76 (TCGA-DD-AAEB.E991576A-60BD-4C11-9B4E-EA43F19D06C3.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).